Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5518, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5518-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] with a PSA of 36. Patient also has a history of [REDACTED]. The patient also has a history of biopsy on [REDACTED]. Prostate tissue right mid – prostatic adenocarcinoma, with a Gleason score: 4+5=9 with ductal features, involving 2 of 2 cores in approximately 70% of the tissue. Total linear extent is 1.2 cm. Perineural invasion is identified. Prostate tissue, right apex, needle biopsy – prostatic adenocarcinoma with a Gleason score: 4+5=9 with ductal features, involving 1 of 1 core in approximately 80% of tissue. Total linear extent is 0.8 cm. Prostate tissue, left base, needle biopsy – prostatic adenocarcinoma, with a Gleason score: 4+5=9 with ductal features, involving 1 of 1 core, in approximately 80% of the tissue. Total linear extent is 0.8 cm. Perineural invasion is identified. Prostate tissue, left mid, needle biopsy – prostatic adenocarcinoma with a Gleason score: 4+5=9 with ductal features, involving 2 of 2 cores in approximately 90% of the tissue. Total linear extent is 2.1 cm. Perineural invasion is identified. Prostate tissue, left apex, needle biopsy – prostatic adenocarcinoma, with a Gleason score: 4+4=8, involving [REDACTED] 95% of the tissue with ductal features. Total linear extent is 0.7 cm. Perineural invasion is identified [REDACTED].

PRE-OP DIAGNOSIS: Prostate cancer.
POST-OP DIAGNOSIS: Same.
PROCEDURE: Radical prostatectomy.

FINAL DIAGNOSIS:

PART 1:

LYMPH NODES, RIGHT PELVIC, EXCISION –
NO EVIDENCE OF NEOPLASIA IN 2 LYMPH NODES.

PART 2:

LYMPH NODES, LEFT PELVIC, EXCISION –
NO EVIDENCE OF NEOPLASIA IN 1 LYMPH NODE.

PART 3:

PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY –

- A. INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE 4+5=9 WITH EXTENSIVE DUCTAL DIFFERENTIATION AND SIGNET RING CELL FEATURES.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 2.3 cm.
- C. THE CARCINOMA INVOLVES 80% OF THE EXAMINED PROSTATE VOLUME.
- D. BILATERAL SEMINAL VESICLES ARE INVOLVED BY CARCINOMA.
- E. THE CARCINOMA SHOWS MULTIFOCAL EXTRACAPSULAR EXTENSION IN THE LEFT AND RIGHT LOBES.
- F. THE CARCINOMA EXTENDS TO THE SURGICAL RESECTION MARGINS IN THE LEFT PROXIMAL URETHRAL MARGIN AND THE RIGHT DISTAL URETHRAL MARGIN (SLIDE 3H, 3I, 1.1 CM).
- G. EXTENSIVE PERINEURAL INVASION IS IDENTIFIED.
- H. ANGIOLYMPHATIC INVASION IS IDENTIFIED (SLIDE 3A).
- I. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. PATHOLOGIC TNM STAGE: pT4 N0 MX.
- K. TNM HISTOLOGIC GRADE = G3-4.
- L. BENIGN PROSTATIC HYPERPLASIA AND CHRONIC INFLAMMATION ARE NOTED.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 36
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	5
GLEASON SUM SCORE:	9
GLEASON 4/5 PERCENTAGE:	90%
WEIGHT OF PROSTATE:	51.60gm
TUMOR SIZE:	Maximum dimension: 2.3 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	> 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Multifocal
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	Yes
SEMINAL VESICLE INVASION:	Yes
SURGICAL MARGIN INVOLVEMENT:	Focal tumor involvement at margin
LYMPH NODES EXAMINED:	3
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT4
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

TCGA - EJ - 5518

Source: NCI Genomic Data Commons file 6152b2b2-b7ca-460e-82dc-7866ce3e93cd (TCGA-EJ-5518.8299FF67-BED6-462F-87AD-3C8BE45E1453.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).